Somatic mutation profile of tumor specimen TCGA-CV-7411-01A (aliquot TCGA-CV-7411-01A-11D-2078-08) from TCGA case TCGA-CV-7411, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 64.9 years (23,696 days).
Specimen TCGA-CV-7411-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ca2ff9d-254e-45ed-a090-3f85d8a79acd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7411-10A (Blood Derived Normal), aliquot TCGA-CV-7411-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82f4ba18-330e-427a-8019-e68363acbfff

The open-access MAF lists 122 somatic variants for this specimen: 92 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 29, Nonsense Mutation 7, Frame Shift Del 4, Frame Shift Ins 2, Splice Site 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 17/84 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs755655007, COSV99367987; called by muse, mutect2
- ABCB4 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0.015); catalogued as COSV99711257; called by muse, mutect2, varscan2
- ADGRG4 | c.2828C>T p.S943L | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV99796717; called by muse, mutect2, varscan2
- AGAP1 | c.2419G>A p.A807T (on ENST00000304032 / NM_001037131.3; = p.A754T on NM_014914.5) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.388); catalogued as rs1449589613, COSV100367061; called by muse, mutect2, varscan2
- AKAP8 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV54104460, COSV99512165; called by muse, mutect2, varscan2
- AKNAD1 | c.1219C>G p.P407A | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.388); catalogued as rs1296747975, COSV100645862; called by muse, mutect2, varscan2
- ASPM | c.1835C>T p.S612L | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV54130515; called by muse, mutect2, varscan2
- ATP2A1 | c.1417T>C p.S473P | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); catalogued as COSV100837397; called by muse, mutect2, varscan2
- ATP7A | c.943A>T p.R315W | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100431678; called by muse, mutect2, varscan2
- BOD1L1 | c.5536G>T p.A1846S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99238327; called by muse, mutect2, varscan2
- C11orf68 | c.505C>T p.R169C (on ENST00000530188; = p.R210C on NM_031450.4) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV56988053; called by muse, mutect2, varscan2
- C12orf42 | c.95T>G p.I32S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100172823; called by muse, mutect2, varscan2
- CCSER1 | c.1630G>A p.V544I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV61456648; called by muse, mutect2
- CEP152 | c.2611C>T p.P871S | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100359141; called by muse, mutect2, varscan2
- CEP41 | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs781856872, COSV99782931; called by muse, mutect2, varscan2
- CHD2 | c.4366A>T p.I1456F | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV101245977; called by muse, mutect2, varscan2
- CLMN | c.2845G>A p.A949T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV100112418; called by muse, mutect2, varscan2
- CLSTN2 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as rs762157350, COSV71726191; called by muse, mutect2, varscan2
- CPS1 | c.1512A>T p.L504F | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99244054; called by muse, mutect2, varscan2
- CRIM1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54864255; called by muse, mutect2, varscan2
- DHRS7B | c.820C>G p.Q274E | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.024); catalogued as COSV100684078; called by muse, mutect2, varscan2
- DOCK2 | c.4759C>A p.H1587N | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV56959377, COSV99915305; called by muse, mutect2, varscan2
- DRC7 | c.2272C>A p.L758I | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.227); catalogued as COSV100395895; called by muse, mutect2, varscan2
- DRP2 | c.848C>A p.S283Y | Missense Mutation (SNP) | VAF 47/289 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV100871740, COSV100872065; called by muse, mutect2, varscan2
- DSG2 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV55198504, COSV99853545; called by muse, mutect2, varscan2
- FAT2 | c.7839T>G p.D2613E | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99944070; called by muse, mutect2, varscan2
- FAT4 | c.6138T>A p.D2046E | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100630120; called by muse, mutect2, varscan2
- FMNL3 | c.2128G>C p.E710Q | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99526970; called by muse, mutect2, varscan2
- FMO4 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV100882171; called by muse, mutect2, varscan2
- FRYL | c.7546G>T p.E2516* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV99978092; called by muse, mutect2, varscan2
- GOT1L1 | c.872A>G p.N291S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100294710; called by muse, mutect2, varscan2
- GRIA4 | c.1923C>A p.N641K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99234434; called by muse, mutect2, varscan2
- GRIN2B | c.4270C>T p.L1424F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.15); catalogued as rs748128078, COSV101663185; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- H4C5 | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV63486069; called by muse, mutect2, varscan2
- HAVCR2 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs568064038, COSV100324980; called by muse, mutect2
- HELQ | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.244); catalogued as COSV99788125; called by muse, mutect2, varscan2
- JCAD | c.2945C>G p.S982* | Nonsense Mutation (SNP) | VAF 31/130 reads (24%) | catalogued as COSV100948563; called by muse, mutect2, varscan2
- JCAD | c.2806C>T p.R936C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV64761899; called by muse, mutect2, varscan2
- KCNA4 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100069261; called by muse, mutect2, varscan2
- LRRTM1 | c.734T>A p.V245E | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV99703162, COSV99703436; called by muse, mutect2, varscan2
- MAP2 | c.2698A>C p.T900P | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV99561648; called by muse, mutect2, varscan2
- MCCC2 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100040543; called by muse, mutect2, varscan2
- MICB | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as rs1228851722, COSV99357586; called by muse, mutect2, varscan2
- MIDN | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1333492951, COSV56294789; called by muse, mutect2
- MRC2 | c.978G>C p.Q326H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV100316759; called by muse, mutect2, varscan2
- MTF1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs1371060530, COSV100888572; called by muse, mutect2, varscan2
- MYOM1 | c.3464C>T p.S1155L | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.43); PolyPhen probably damaging (1); catalogued as COSV55291935; called by muse, mutect2, varscan2
- NES | c.1952C>T p.T651M | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs746512716, COSV63960511; called by muse, mutect2, varscan2
- NF1 | c.7661C>T p.P2554L (on ENST00000358273 / NM_001042492.3; = p.P2533L on NM_000267.3) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.155); catalogued as rs756138226, COSV100648232; called by muse, mutect2, varscan2
- NLRP9 | c.2000C>T p.T667I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.223); catalogued as COSV100243433; called by muse, mutect2
- NOTCH1 | c.3675C>A p.C1225* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99491602; called by muse, mutect2
- OGDHL | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as rs1166580809, COSV100934508; called by muse, mutect2, varscan2
- P2RX1 | c.913C>G p.R305G | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV56653077, COSV99844945; called by muse, mutect2, varscan2
- PADI2 | c.729del p.G244Afs*39 | Frame Shift Del (DEL) | VAF 7/81 reads (9%) | catalogued as rs753328161; called by mutect2, pindel
- PAPSS2 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as rs1355794195, COSV63263963; called by muse, mutect2, varscan2
- PKD1L1 | c.3463A>G p.T1155A | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV56959295; called by muse, mutect2, varscan2
- PLCG1 | c.1268G>A p.R423K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as COSV99719267; called by muse, mutect2, varscan2
- PLXNC1 | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.745); catalogued as rs773924211, COSV51573275, COSV51573296; called by muse, mutect2, varscan2
- PRDM9 | c.2347C>T p.R783W | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs566721769, COSV57005773, COSV99690900; called by muse, varscan2
- RBCK1 | c.958G>T p.E320* (on ENST00000356286 / NM_031229.4; = p.E278* on NM_006462.6) | Nonsense Mutation (SNP) | VAF 22/99 reads (22%) | catalogued as COSV100675963; called by muse, mutect2, varscan2
- RBM12B | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as rs759904690, COSV101197162; called by muse, mutect2, varscan2
- RGMA | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV100224674; called by muse, mutect2
- RNF111 | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 20/251 reads (8%) | catalogued as COSV100789195; called by muse, mutect2
- RPGRIP1 | c.1459C>G p.Q487E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV52844543, COSV52845472; called by muse, mutect2, varscan2
- RYR2 | c.5771C>T p.A1924V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV100772845; called by muse, mutect2
- SCAF4 | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV99742137; called by muse, mutect2, varscan2
- SCAF8 | c.2504C>T p.S835F | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100914273; called by muse, mutect2, varscan2
- SCN1A | c.4316A>G p.Y1439C (on ENST00000303395 / NM_001202435.3; = p.Y1428C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100322048; called by muse, mutect2, varscan2
- SDR42E1 | c.592C>A p.P198T | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100200792; called by muse, mutect2, varscan2
- SEMA5B | c.3116C>T p.A1039V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV99533163; called by muse, mutect2
- SERPINA1 | c.895T>G p.F299V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.19); catalogued as COSV63345528, COSV63345578; called by muse, mutect2, varscan2
- SLC15A1 | c.363C>T p.H121= | Splice Region (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100918248; called by muse, mutect2, varscan2
- SPTAN1 | c.1807G>T p.D603Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100824000; called by muse, mutect2, varscan2
- SREBF2 | c.752A>T p.D251V | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV100761549; called by muse, mutect2, varscan2
- STAB1 | c.4761+1G>C p.X1587_splice | Splice Site (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100402216; called by muse, mutect2, varscan2
- SYNE1 | c.15435C>A p.H5145Q (on ENST00000367255 / NM_182961.4; = p.H5074Q on NM_033071.3) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.863); catalogued as COSV99578114; called by mutect2, varscan2
- TBX2 | c.46T>A p.F16I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV99539142; called by muse, mutect2
- TECTA | c.2398T>C p.F800L | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV50774291, COSV99081211; called by muse, mutect2, varscan2
- TGFBR2 | c.1375T>C p.S459P | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99848110; called by muse, mutect2, varscan2
- TNFRSF13C | c.325C>G p.R109G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52169225, COSV99351674, COSV99351810; called by mutect2, varscan2
- TRPC3 | c.2663G>A p.R888H (on ENST00000379645 / NM_001366479.2; = p.R815H on NM_003305.2) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV53375170; called by muse, mutect2, varscan2
- UNC13B | c.2892C>A p.N964K | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101037290; called by muse, mutect2, varscan2
- USP29 | c.2104G>C p.E702Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.889); catalogued as COSV99518644; called by muse, mutect2, varscan2
- VPS11 | c.147C>A p.F49L (on ENST00000620429; = p.F593L on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100333998; called by muse, mutect2, varscan2
- ACACA | c.995A>T p.D332V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ANO3 | c.989_990del p.L330Hfs*14 | Frame Shift Del (DEL) | VAF 15/96 reads (16%) | called by mutect2, pindel, varscan2
- DSG3 | c.1998del p.H667Ifs*23 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- GALNT13 | c.731del p.T244Ifs*10 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | called by mutect2, pindel, varscan2
- ICAM1 | c.1369dup p.C457Lfs*24 | Frame Shift Ins (INS) | VAF 4/47 reads (9%) | called by mutect2, pindel
- RPL22 | c.104dup p.D35Efs*6 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- AGAP1 | c.2418G>T p.L806= (on ENST00000304032 / NM_001037131.3; = p.L753= on NM_014914.5) | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100367060; called by muse, mutect2, varscan2
- ALPP | c.162C>T p.A54= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as rs201263533, COSV101235188; called by muse, mutect2, varscan2
- ANK3 | c.5652C>A p.P1884= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV99782289; called by muse, varscan2
- AOC2 | c.1089A>T p.V363= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as COSV99513802; called by muse, mutect2, varscan2
- BRINP1 | c.1092C>T p.F364= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs764461621, COSV56310696, COSV56314450; called by muse, mutect2, varscan2
- C1QTNF9B | c.741G>T p.G247= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as rs775722443, COSV101158634; called by muse, varscan2
- CCDC180 | c.4761C>A p.L1587= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV100827307; called by muse, mutect2, varscan2
- CHAF1B | c.546G>A p.L182= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100023760; called by muse, mutect2, varscan2
- CNGA3 | c.1644G>A p.G548= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV99737439; called by muse, mutect2, varscan2
- DHX38 | c.2463C>A p.I821= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV99194576; called by muse, mutect2, varscan2
- DNAJB6 | c.903G>A p.L301= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV100056031; called by muse, mutect2, varscan2
- ENPP1 | c.1584A>G p.K528= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV100719644; called by muse, mutect2, varscan2
- FCRL3 | c.1125C>A p.T375= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs778553895, COSV100943538; called by muse, mutect2, varscan2
- GCN1 | c.4260G>T p.A1420= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV100325952; called by muse, mutect2, varscan2
- HDAC9 | c.1914C>T p.D638= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV101287483; called by muse, mutect2, varscan2
- IGKV1D-17 | c.96C>T p.A32= | Silent (SNP) | VAF 36/255 reads (14%) | called by muse, mutect2, varscan2
- KCNU1 | c.984C>G p.L328= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV101299422; called by muse, mutect2, varscan2
- KIAA1210 | c.2445C>T p.F815= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV101274387; called by mutect2, varscan2
- L1CAM | c.732C>T p.F244= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100649464; called by muse, mutect2
- MRPS15 | c.141C>G p.L47= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100118216; called by muse, mutect2, varscan2
- NLRP9 | c.444G>A p.V148= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100243434; called by muse, mutect2, varscan2
- OR6B3 | c.874C>T p.L292= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as rs1476858600, COSV100097656; called by muse, mutect2, varscan2
- PCDHB2 | c.2328C>T p.F776= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as COSV50564143, COSV50602593; called by muse, mutect2, varscan2
- PLXNA2 | c.5253G>T p.V1751= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100885924; called by muse, mutect2, varscan2
- POGZ | c.3909C>G p.V1303= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV99305277; called by muse, mutect2, varscan2
- PSD | c.2622C>T p.P874= | Silent (SNP) | VAF 41/148 reads (28%) | catalogued as COSV99193915; called by muse, mutect2, varscan2
- RNF214 | c.1284G>A p.L428= | Silent (SNP) | VAF 31/177 reads (18%) | catalogued as COSV100327013; called by muse, mutect2, varscan2
- RYR3 | c.11001A>G p.L3667= (on ENST00000389232; = p.L3668= on NM_001036.6) | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV101214495; called by muse, mutect2
- SEC14L4 | c.1068C>T p.L356= | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as rs141872549; called by muse, mutect2
- UCP2 | c.-1C>G | 5'UTR (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100135187; called by muse, mutect2, varscan2
